Somatic mutation profile of tumor specimen MP2PRT-PAPSEW-TMP1-A (aliquot MP2PRT-PAPSEW-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPSEW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,337 days).
Specimen MP2PRT-PAPSEW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4894670e-e486-4a83-a354-928d77a9fc3f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPSEW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPSEW-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be221deb-942b-4c18-a6d3-7c9487dc9eac

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.3694G>A p.G1232S | Missense Mutation (SNP) | VAF 144/399 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV60785813, COSV60799159; called by muse, mutect2, varscan2
- PVRIG | c.240dup p.N81Qfs*61 | Frame Shift Ins (INS) | VAF 150/552 reads (27%) | catalogued as rs1563026510, COSV52782511; called by mutect2, pindel, varscan2
- COL4A1 | c.1243C>A p.P415T | Missense Mutation (SNP) | VAF 164/347 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- NCOR1 | c.1139_1140insAGGGGTAGTGGCCCT p.I380_S381insGVVAL | In Frame Ins (INS) | VAF 64/84 reads (76%) | called by mutect2, pindel*, varscan2*
- SLC7A2 | c.1654C>A p.Q552K (on ENST00000494857 / NM_001370338.1; = p.Q591K on NM_003046.6) | Missense Mutation (SNP) | VAF 97/205 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPRS1 | c.78C>T p.D26= | Silent (SNP) | VAF 122/303 reads (40%) | catalogued as rs767341872, COSV100859275; called by muse, mutect2, varscan2
